Gene-level copy-number profile of tumor specimen TCGA-30-1866-01A from TCGA case TCGA-30-1866, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 61.8 years (22,562 days).
Specimen TCGA-30-1866-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ba4acff6-1f39-4b71-9016-1138025e3165.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1866-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67928d42-d1fd-4d03-a507-6aca5d365884

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 200; copy number 2: 11,265; copy number 3: 17,183; copy number 4: 23,918; copy number 5: 4,906; copy number 6: 170; copy number 7: 389; copy number 8: 424; copy number 9: 403; copy number 10: 506; copy number 11: 59; copy number 12: 218; copy number 14: 135.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1866-01): tumor purity 0.85, ploidy 3.59, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:10,729,777–10,880,895, 1 gene (within-gene range 0–2): AC015908.7.
- chr17:10,792,059–12,991,643, 30 genes (within-gene range 0–2): AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,321 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,262,109, 84 genes, copy number 10 (broad region; genes not listed).
- chr4:2,295,584–2,325,082, 3 genes, copy number 10: AL158068.2, RN7SL589P, AL158068.1.
- chr4:5,897,373–8,619,761, 58 genes, copy number 9 (within-gene range 3–9): C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274, AFAP1-AS1, AFAP1, AC112254.1, AC097381.1, ABLIM2, MIR95, AC097381.3, AC097381.2, GMPSP1, SH3TC1, HTRA3, LINC02517, AC104825.1, ACOX3, RNA5SP152, TRMT44, AC105345.2, AC105345.1, GPR78, CPZ.
- chr5:34,651,457–37,249,421, 46 genes, copy number 9–11 (within-gene range 5–11): AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2.
- chr5:38,682,070–40,431,491, 22 genes, copy number 9: AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1.
- chr14:18,333,726–30,573,629, 525 genes, copy number 10–12 (within-gene range 4–12) (broad region; genes not listed).
- chr19:10,350,529–16,660,442, 369 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr19:50,861,568–51,442,650, 58 genes, copy number 11 (within-gene range 4–11): KLK2, KLKP1, KLK4, PPIAP59, KLK5, AC011483.2, KLK6, AC011483.3, AC011483.1, KLK7, KLK8, AC011473.4, KLK9, KLK10, AC011473.2, KLK11, KLK12, AC011473.3, AC011473.1, KLK13, KLK14, CTU1, SIGLEC18P, SIGLEC9, AC063977.2, SIGLEC7, AC063977.1, AC063977.5, AC063977.6, SIGLEC17P, SIGLEC20P, AC063977.4, SIGLEC21P, MIR8074, SIGLEC22P, CD33, SIGLECL1, AC063977.3, LINC01872, SIGLEC24P, IGLON5, VSIG10L, AC008750.2, AC008750.3, ETFB, AC008750.7, AC008750.4, CLDND2, NKG7, LIM2, C19orf84, AC008750.6, NIFKP6, SIGLEC10, AC008750.1, SIGLEC10-AS1, AC008750.5, AC020914.5.
- chr19:54,294,049–55,180,289, 73 genes, copy number 12 (broad region; genes not listed).
- chr19:55,947,832–57,447,101, 82 genes, copy number 10–14 (within-gene range 5–14) (broad region; genes not listed).
- chr20:15,892,355–15,985,876, 1 gene, copy number 9 (within-gene range 3–9): AL079338.1.

Autosomal genes at a single copy (total copy number 1): 200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
